Somatic mutation profile of tumor specimen C3L-00598-02 (aliquot CPT0019410010) from CPTAC case C3L-00598, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 61.5 years (22,466 days).
Specimen C3L-00598-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 611fecc7-34e4-4047-9767-833cde7af8e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00598-31 (Blood Derived Normal), aliquot CPT0019480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b24e7a5-9a2d-4fc9-b1d0-c675d2e62bb9

The open-access MAF lists 59 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 13, Intron 5, Nonsense Mutation 3, Splice Site 3, In Frame Del 2, 5'UTR 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 92/331 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 96/336 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as rs1171419424; called by muse, mutect2, varscan2
- ABCA10 | c.4222G>A p.D1408N | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52218253; called by muse, mutect2, varscan2
- ANOS1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 112/730 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144620955, COSV52916486; called by muse, mutect2, varscan2
- CASP14 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs143520169; called by muse, mutect2, varscan2
- CLEC18A | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 4/357 reads (1%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs764034494; called by muse, mutect2
- HTR3B | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs770088313, COSV52746850; called by muse, mutect2, varscan2
- IGSF8 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV58757715; called by muse, mutect2, varscan2
- KCNC3 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 178/884 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100979391, COSV65387131; called by muse, mutect2, varscan2
- MAGEE1 | c.2746C>T p.R916* | Nonsense Mutation (SNP) | VAF 47/243 reads (19%) | catalogued as rs1556839971, COSV63912558; called by muse, mutect2, varscan2
- MAP7D2 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs367603064, COSV65527236; called by muse, mutect2, varscan2
- MAT1A | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 148/733 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs545505182, COSV64747269; called by muse, mutect2, varscan2
- MYH6 | c.2168+1G>A p.X723_splice | Splice Site (SNP) | VAF 133/680 reads (20%) | catalogued as rs1366141531; called by muse, mutect2, varscan2
- OR6S1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs142856316; called by muse, mutect2, varscan2
- P3H2 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs571855250, COSV60020942; called by muse, mutect2, varscan2
- TRAV20 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs369305527; called by muse, mutect2
- USP11 | c.2800C>T p.R934* (on ENST00000218348; = p.R891* on NM_001371072.1) | Nonsense Mutation (SNP) | VAF 41/182 reads (23%) | catalogued as rs1366220290; called by muse, mutect2, varscan2
- ZC4H2 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.472); catalogued as rs372946873, COSV62005205; called by muse, mutect2
- ZNF804B | c.3794G>A p.G1265D | Missense Mutation (SNP) | VAF 70/293 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1178257221; called by muse, mutect2, varscan2
- AGXT2 | c.1189-2A>T p.X397_splice | Splice Site (SNP) | VAF 73/346 reads (21%) | called by muse, mutect2, varscan2
- AKAP3 | c.596G>C p.G199A | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.88); called by muse, mutect2
- ALOX12B | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 97/401 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- CLTB | c.580_582del p.K194del (on ENST00000310418 / NM_007097.5; = p.K176del on NM_001834.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 41/354 reads (12%) | called by mutect2, pindel, varscan2
- DNAH2 | c.10872G>A p.M3624I | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- DPEP3 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.538); called by muse, varscan2
- EFCC1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EHD4 | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIPK1 | c.1272G>T p.R424S | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IRF2BP1 | c.1472G>A p.S491N | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNV1 | c.1361T>G p.L454R | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- NINL | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RBPJ | c.1425_1430del p.N476_S477del | In Frame Del (DEL) | VAF 87/499 reads (17%) | called by mutect2, pindel, varscan2
- SCN10A | c.270+1del p.X90_splice | Splice Site (DEL) | VAF 44/183 reads (24%) | called by mutect2, pindel, varscan2
- SCN7A | c.2759G>A p.W920* | Nonsense Mutation (SNP) | VAF 15/182 reads (8%) | called by muse, mutect2
- SI | c.4106C>T p.S1369F | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF208 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- ARID5A | c.1662C>T p.F554= | Silent (SNP) | VAF 45/252 reads (18%) | catalogued as rs770664548; called by muse, mutect2, varscan2
- DOCK1 | c.1509C>T p.D503= | Silent (SNP) | VAF 70/408 reads (17%) | catalogued as rs370668962; called by muse, mutect2, varscan2
- MYO10 | c.5937C>T p.A1979= | Silent (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- NCOA2 | c.4335C>T p.N1445= | Silent (SNP) | VAF 66/349 reads (19%) | catalogued as rs767106389; called by muse, mutect2, varscan2
- NUP188 | c.1722G>A p.K574= | Silent (SNP) | VAF 66/236 reads (28%) | called by muse, mutect2, varscan2
- OPCML | c.375G>A p.T125= | Silent (SNP) | VAF 48/223 reads (22%) | catalogued as rs548104590, COSV59419763; called by muse, mutect2, varscan2
- PEX6 | c.2724G>A p.Q908= | Silent (SNP) | VAF 145/832 reads (17%) | called by muse, mutect2, varscan2
- PTK2B | c.498C>T p.Y166= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs527933742; called by muse, mutect2, varscan2
- SLC1A6 | c.765G>A p.E255= | Silent (SNP) | VAF 106/428 reads (25%) | called by muse, mutect2, varscan2
- SLC35B1 | c.33G>T p.R11= | Silent (SNP) | VAF 71/264 reads (27%) | catalogued as rs777342365; called by muse, mutect2, varscan2
- TOX2 | c.240G>A p.P80= (on ENST00000358131 / NM_001098798.2; = p.P29= on NM_032883.3) | Silent (SNP) | VAF 51/250 reads (20%) | catalogued as rs774698912, COSV57881921; called by muse, mutect2, varscan2
- TRPC7 | c.471C>T p.D157= | Silent (SNP) | VAF 37/174 reads (21%) | catalogued as rs753491646, COSV61456624; called by muse, mutect2, varscan2
- UBR3 | c.5277G>A p.Q1759= | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as rs1483286620, COSV99774142; called by muse, varscan2
- ADGRV1 | c.13083-47dup | Intron (INS) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as rs73150876; called by muse, mutect2
- CRMP1 | chr4:5892632 C>T | 5'Flank (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- GRN | c.265-13C>T | Intron (SNP) | VAF 60/382 reads (16%) | called by muse, mutect2, varscan2
- HELT | c.*2G>A | 3'UTR (SNP) | VAF 10/54 reads (19%) | catalogued as rs1393979575, COSV100132915; called by muse, mutect2, varscan2
- KCNAB1 | c.276-147980T>C | Intron (SNP) | VAF 50/251 reads (20%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12937C>T | Intron (SNP) | VAF 37/155 reads (24%) | catalogued as rs1362544470; called by muse, mutect2, varscan2
- SLC29A2 | c.-14C>A | 5'UTR (SNP) | VAF 62/337 reads (18%) | catalogued as rs1185429614; called by muse, mutect2, varscan2
- SLC29A2 | c.-15T>A | 5'UTR (SNP) | VAF 60/337 reads (18%) | called by muse, mutect2, varscan2
